Somatic mutation profile of tumor specimen HCM-BROD-0648-C71-02A (aliquot HCM-BROD-0648-C71-02A-01D-A83U-36) from HCMI case HCM-BROD-0648-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,260 days).
Specimen HCM-BROD-0648-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73c7699c-de3e-4a06-8597-e05ad5c41a3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0648-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0648-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d7dc12f-fe85-4339-b187-2f208481179c

The open-access MAF lists 1,540 somatic variants for this specimen: 965 protein-altering or splice-affecting, 516 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 870, Silent 516, Nonsense Mutation 45, Intron 33, Splice Site 26, Splice Region 14, 3'UTR 10, 5'UTR 7, Frame Shift Del 7, 5'Flank 4, RNA 4, Translation Start Site 2.

Variants (750 of 1,540; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSP | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 124/339 reads (37%) | catalogued as rs1267435790; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.892del p.Q298Kfs*9 | Frame Shift Del (DEL) | VAF 305/465 reads (66%) | catalogued as rs786204884, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTS | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200712908, CM971283; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 212/624 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs786205514; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1006+1G>A p.X336_splice | Splice Site (SNP) | VAF 74/167 reads (44%) | catalogued as rs367947986; called by muse, mutect2, varscan2
- ABCA7 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 291/809 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54031160; called by muse, mutect2, varscan2
- ABCC11 | c.2475G>A p.W825* | Nonsense Mutation (SNP) | VAF 187/428 reads (44%) | catalogued as rs750609137, COSV62322921; called by muse, mutect2, varscan2
- ABCG4 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 214/629 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV56645023; called by muse, mutect2, varscan2
- AC011005.1 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 315/758 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs540175247, COSV71956058; called by muse, mutect2, varscan2
- ACACA | c.4012G>A p.D1338N | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1567811808; called by muse, mutect2, varscan2
- ADAM12 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 127/431 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767462610, COSV64103375, COSV64115761; called by muse, mutect2, varscan2
- ADAM28 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 134/348 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs377655974; called by muse, mutect2, varscan2
- ADAR | c.18G>A p.G6= | Splice Region (SNP) | VAF 99/289 reads (34%) | catalogued as COSV52715332; called by muse, mutect2, varscan2
- ADCY2 | c.2209C>T p.L737F | Missense Mutation (SNP) | VAF 184/252 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs768750286, COSV100601444; called by muse, mutect2, varscan2
- ADGRG4 | c.5926G>A p.E1976K | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99796083; called by muse, mutect2
- ADGRV1 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 143/398 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67979912; called by muse, mutect2, varscan2
- ADRM1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 157/587 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1568867381; called by muse, mutect2, varscan2
- ADSL | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 242/577 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1235670046; called by muse, mutect2, varscan2
- AFTPH | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 257/687 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV53216064; called by muse, mutect2, varscan2
- AHNAK | c.9814C>T p.P3272S | Missense Mutation (SNP) | VAF 159/460 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57207513; called by muse, mutect2, varscan2
- AIFM2 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as COSV57158490; called by muse, mutect2, varscan2
- AJM1 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 212/657 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV99915829; called by muse, mutect2, varscan2
- AK7 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 263/711 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs1484637749, COSV50869092; called by muse, mutect2, varscan2
- AKAP13 | c.3100G>A p.G1034R | Missense Mutation (SNP) | VAF 292/748 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.564); catalogued as rs1426234742; called by muse, mutect2
- AMBP | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 141/403 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs769729448; called by muse, mutect2, varscan2
- ANAPC1 | c.5086G>A p.V1696I | Missense Mutation (SNP) | VAF 101/455 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs755821664, COSV100594925; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 160/487 reads (33%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs775180361, COSV51843131; called by muse, mutect2, varscan2
- ANKRD10 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 75/543 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV57445931; called by muse, mutect2, varscan2
- ANKRD44 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 164/536 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1344707152; called by muse, mutect2, varscan2
- AP3B1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1326425026; called by muse, mutect2, varscan2
- AR | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 19/598 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV65953710, COSV65965180; called by muse, mutect2
- ARHGEF11 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1267531073; called by muse, mutect2, varscan2
- ARHGEF37 | c.1808C>T p.T603I | Missense Mutation (SNP) | VAF 152/397 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100382096; called by muse, mutect2
- ARHGEF4 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 175/442 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752871941; called by muse, mutect2, varscan2
- ARL8A | c.372+1G>A p.X124_splice | Splice Site (SNP) | VAF 122/328 reads (37%) | catalogued as COSV55343159; called by muse, mutect2, varscan2
- ASPG | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 190/496 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV101496444; called by muse, mutect2, varscan2
- ASPM | c.9636+1G>A p.X3212_splice | Splice Site (SNP) | VAF 72/218 reads (33%) | catalogued as COSV99659529; called by muse, mutect2, varscan2
- ATF6B | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 221/573 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1302296817; called by muse, mutect2, varscan2
- ATG9B | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 372/975 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756859140; called by muse, mutect2, varscan2
- ATP1A1 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 134/457 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs760128653; called by muse, mutect2, varscan2
- ATP2C2 | c.2015C>T p.T672I | Missense Mutation (SNP) | VAF 223/575 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs775774214; called by muse, mutect2, varscan2
- ATP5ME | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 132/390 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as rs1219335688, COSV55325324; called by muse, mutect2, varscan2
- ATP8A1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 149/371 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs199599944; called by muse, mutect2, varscan2
- BIRC2 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 121/337 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs368571070; called by muse, mutect2, varscan2
- BRIP1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 225/559 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs748793974; called by muse, mutect2, varscan2
- BSND | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 282/703 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV104428859; called by muse, mutect2, varscan2
- BTN3A3 | c.1601C>T p.T534I | Missense Mutation (SNP) | VAF 222/580 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs1260771375; called by muse, mutect2, varscan2
- BX255925.3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 212/550 reads (39%) | SIFT deleterious, low confidence (0); catalogued as rs922894110; called by muse, mutect2, varscan2
- C14orf39 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58781638; called by muse, mutect2, varscan2
- C16orf96 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 24/858 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1361810252; called by muse, mutect2
- C1orf198 | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 24/759 reads (3%) | catalogued as rs1476540206; called by muse, mutect2
- C1orf35 | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 193/568 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); catalogued as rs1304723113; called by muse, mutect2, varscan2
- C2CD4B | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 30/1084 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs927332105; called by muse, mutect2
- C4orf46 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 198/573 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.948); catalogued as rs747196215; called by muse, mutect2, varscan2
- CABIN1 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 123/389 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.186); catalogued as rs749581794; called by muse, mutect2, varscan2
- CACNA1F | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 265/359 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59904104; called by muse, mutect2, varscan2
- CARD11 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 190/535 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV62756393, COSV62756695; called by muse, mutect2, varscan2
- CARD14 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 129/410 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs200837077, COSV100712606; called by muse, mutect2, varscan2
- CATSPERB | c.2260+1G>A p.X754_splice | Splice Site (SNP) | VAF 118/290 reads (41%) | catalogued as rs753798941; called by muse, mutect2, varscan2
- CATSPERB | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 177/442 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764572295; called by muse, mutect2, varscan2
- CBX8 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 329/825 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV53936620; called by muse, mutect2, varscan2
- CCBE1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 152/435 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as COSV67950364; called by muse, mutect2, varscan2
- CCDC39 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1347216428; called by muse, mutect2, varscan2
- CCNK | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 26/852 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs1198806194; called by muse, mutect2
- CDHR5 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 214/661 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.187); catalogued as rs1320029759, COSV57643579; called by muse, varscan2
- CDKN1B | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 192/527 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV99964006; called by muse, mutect2, varscan2
- CEACAM21 | c.701-1G>A p.X234_splice | Splice Site (SNP) | VAF 158/427 reads (37%) | catalogued as rs782046893, COSV51816816; called by muse, mutect2, varscan2
- CECR2 | c.3898G>A p.E1300K (on ENST00000342247 / NM_001290047.2; = p.E1116K on NM_001290046.1) | Missense Mutation (SNP) | VAF 205/546 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV52842345; called by muse, mutect2, varscan2
- CEL | c.1508G>A p.G503D (on ENST00000673714; = p.G500D on NM_001807.6) | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs781764359; called by muse, mutect2, varscan2
- CEP250 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 145/642 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765592288; called by muse, mutect2, varscan2
- CEP95 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 13/440 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1159215679; called by muse, mutect2
- CFAP221 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 119/348 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs555779073; called by muse, mutect2, varscan2
- CHD7 | c.3347A>G p.K1116R | Missense Mutation (SNP) | VAF 285/682 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs750214154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHIT1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 202/571 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV55148814; called by muse, mutect2, varscan2
- CHRNA4 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 181/659 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100937407; called by muse, mutect2, varscan2
- CHTF18 | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1053922818, COSV50210383; called by muse, mutect2, varscan2
- CLSTN3 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 165/547 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as rs1181638108, COSV56939595; called by muse, mutect2, varscan2
- CLTRN | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 215/281 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs774293078; called by muse, mutect2, varscan2
- COL14A1 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1442576303, COSV52870305; called by muse, mutect2, varscan2
- COL16A1 | c.2234G>A p.G745D | Missense Mutation (SNP) | VAF 304/793 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778878265; called by muse, mutect2, varscan2
- COL20A1 | c.3815C>T p.P1272L | Missense Mutation (SNP) | VAF 285/1077 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs769122508; called by muse, mutect2, varscan2
- COQ8A | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 233/688 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1172666352; called by muse, mutect2, varscan2
- CPT1B | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56415132; called by muse, mutect2, varscan2
- CRYBG2 | c.4616G>A p.G1539E | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as COSV100366745; called by muse, mutect2, varscan2
- CSE1L | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 121/535 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs772598608; called by muse, mutect2, varscan2
- CTNS | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 157/422 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1110323; called by muse, mutect2, varscan2
- CUBN | c.4645C>T p.L1549F | Missense Mutation (SNP) | VAF 116/386 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV104428221; called by muse, mutect2, varscan2
- CYP2W1 | c.488-1G>A p.X163_splice | Splice Site (SNP) | VAF 223/523 reads (43%) | catalogued as COSV100417289; called by muse, mutect2, varscan2
- DCC | c.3337G>A p.V1113I | Missense Mutation (SNP) | VAF 192/577 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.348); catalogued as COSV101473555; called by muse, mutect2, varscan2
- DCHS2 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 30/1024 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1193501167; called by muse, mutect2
- DCLRE1A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 197/524 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1564846981; called by muse, mutect2, varscan2
- DDIT4 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 195/584 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1291014156; called by muse, mutect2, varscan2
- DIDO1 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 141/582 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as rs1278971358; called by muse, mutect2, varscan2
- DLK2 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 29/1014 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99767659; called by muse, mutect2
- DLK2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 25/834 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1168032564, COSV55087602, COSV99767428; called by muse, mutect2
- DLST | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 144/367 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs765753530; called by muse, mutect2, varscan2
- DMXL1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 179/528 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs771966642; called by muse, mutect2, varscan2
- DNMT3A | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 206/593 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1191994998, COSV53037637; called by muse, mutect2, varscan2
- DOCK11 | c.5536G>A p.E1846K | Missense Mutation (SNP) | VAF 122/189 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99353700; called by muse, mutect2, varscan2
- DOCK5 | c.3985G>A p.E1329K | Missense Mutation (SNP) | VAF 143/464 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs534293524, COSV52408770, COSV99376196; called by muse, mutect2
- DPP10 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 136/384 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.472); catalogued as COSV59725034; called by muse, mutect2, varscan2
- DSP | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 270/628 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs374283517; called by muse, mutect2, varscan2
- EEF1D | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 281/719 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.437); catalogued as rs1297338083; called by muse, mutect2, varscan2
- EFL1 | c.91+1G>A p.X31_splice | Splice Site (SNP) | VAF 147/319 reads (46%) | catalogued as COSV51604773; called by muse, mutect2, varscan2
- EFNB3 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 213/666 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs756748450; called by muse, mutect2, varscan2
- EGFR | c.1577G>A p.C526Y | Missense Mutation (SNP) | VAF 252/2457 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99293406; called by muse, mutect2, varscan2
- EIF2B5 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 148/425 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs1434577522, COSV99889413; called by muse, mutect2, varscan2
- EPHB2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 285/666 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs762351366; called by muse, varscan2
- ESF1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs945949809; called by muse, mutect2, varscan2
- FAM102A | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 139/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770832940; called by muse, mutect2, varscan2
- FAM133B | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1383580765, COSV101300226; called by muse, mutect2, varscan2
- FAM53A | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 233/674 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV57403186; called by muse, mutect2, varscan2
- FBN2 | c.6407G>A p.W2136* | Nonsense Mutation (SNP) | VAF 179/497 reads (36%) | catalogued as COSV52497757; called by muse, mutect2, varscan2
- FBXO22 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs945582178; called by muse, mutect2, varscan2
- FLCN | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 145/420 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1456509027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLII | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 264/755 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1030457573; called by muse, mutect2, varscan2
- FMNL3 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 168/414 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV53300117; called by muse, mutect2, varscan2
- FOXP4 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 171/449 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1221634286; called by muse, mutect2, varscan2
- FREM1 | c.6383G>A p.G2128D | Missense Mutation (SNP) | VAF 224/323 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.16); catalogued as rs367864890; called by muse, mutect2, varscan2
- FRY | c.7736C>T p.S2579F | Missense Mutation (SNP) | VAF 181/499 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs913144111, COSV66574379; called by muse, mutect2, varscan2
- GABRP | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267600549, COSV99517011; called by muse, mutect2, varscan2
- GAK | c.3344G>A p.G1115D | Missense Mutation (SNP) | VAF 30/1026 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV58506234; called by muse, mutect2
- GALK2 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1342680144; called by muse, mutect2, varscan2
- GBA | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 194/569 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM077546; called by muse, mutect2, varscan2
- GFAP | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 107/395 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53648816; called by muse, mutect2, varscan2
- GID8 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 226/742 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs772878499, COSV56611509, COSV56611890; called by muse, mutect2, varscan2
- GLDN | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 238/652 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); catalogued as rs779389882; called by muse, mutect2, varscan2
- GMPS | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460795082; called by muse, mutect2, varscan2
- GNA11 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 166/514 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs1461947710; called by muse, mutect2, varscan2
- GOLGA6L22 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 75/624 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs578076432; called by muse, mutect2, varscan2
- GPANK1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 386/1092 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1261272958, COSV100788966; called by muse, mutect2, varscan2
- GPRIN2 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 89/1117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1205965063; called by muse, mutect2
- GPS1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 212/586 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV57649557; called by muse, mutect2, varscan2
- GPSM2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV51440786, COSV51443177; called by muse, mutect2
- GRIN2A | c.3575C>T p.T1192I | Missense Mutation (SNP) | VAF 215/628 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs1304220791; called by muse, mutect2, varscan2
- GSG1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 147/384 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs749064336, COSV100189392; called by muse, mutect2, varscan2
- HDHD5 | c.250C>T p.P84S (on ENST00000336737 / NM_033070.3; = p.P54S on NM_017829.5) | Missense Mutation (SNP) | VAF 191/502 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50094161; called by muse, mutect2, varscan2
- HEBP1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 148/396 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs971855887; called by muse, mutect2, varscan2
- HERC1 | c.5779C>T p.P1927S | Missense Mutation (SNP) | VAF 149/432 reads (34%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.994); catalogued as COSV101496912; called by muse, mutect2, varscan2
- HERPUD1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 224/504 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.134); catalogued as COSV55861576; called by muse, varscan2
- HES7 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 251/642 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1350479938; called by muse, mutect2, varscan2
- HNRNPM | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 404/1018 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs375484908; called by muse, varscan2
- HOXD12 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 384/989 reads (39%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.622); catalogued as rs762907983; called by muse, mutect2, varscan2
- HYDIN | c.12926C>T p.P4309L | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1455760595; called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 186/653 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.119); catalogued as rs769619522; called by muse, mutect2, varscan2
- IL10 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 184/509 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV65594310; called by muse, mutect2, varscan2
- IL2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.198); catalogued as rs753445824; called by muse, varscan2
- IL25 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 189/421 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as rs145855015; called by muse, mutect2, varscan2
- ILVBL | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 23/790 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1568333819; called by muse, mutect2
- INPP5F | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 133/419 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104423498; called by muse, mutect2, varscan2
- INSM1 | c.948G>A p.W316* | Nonsense Mutation (SNP) | VAF 408/1569 reads (26%) | catalogued as rs1162929533; called by muse, mutect2, varscan2
- INTS1 | c.6224G>A p.R2075Q | Missense Mutation (SNP) | VAF 224/557 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs1003603356; called by muse, mutect2, varscan2
- INTS1 | c.5551G>A p.D1851N | Missense Mutation (SNP) | VAF 277/824 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs759166691; called by muse, mutect2, varscan2
- ITGA4 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 149/452 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.253); catalogued as COSV59212232; called by muse, mutect2
- ITGA7 | c.1633G>A p.V545I (on ENST00000555728; = p.V501I on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/450 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV57694183; called by muse, mutect2, varscan2
- ITPRIPL1 | c.28G>A p.A10T (on ENST00000439118 / NM_001008949.3; = p.A18T on NM_178495.6) | Missense Mutation (SNP) | VAF 176/472 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63152911; called by muse, mutect2, varscan2
- JAG2 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 272/623 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs755972228; called by muse, mutect2, varscan2
- JHY | c.2240A>T p.E747V | Missense Mutation (SNP) | VAF 212/538 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV57076696; called by muse, mutect2, varscan2
- KANK2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 305/817 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs1412184820; called by muse, mutect2, varscan2
- KCNH6 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 279/671 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs756068734; called by muse, mutect2, varscan2
- KCNMA1 | c.3697G>A p.E1233K (on ENST00000286628 / NM_001161352.2; = p.E1175K on NM_002247.4) | Missense Mutation (SNP) | VAF 126/295 reads (43%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.028); catalogued as rs779739159; called by muse, mutect2, varscan2
- KCNT1 | c.2018G>A p.G673D (on ENST00000488444; = p.G692D on NM_020822.3) | Missense Mutation (SNP) | VAF 327/823 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs922840311; called by muse, varscan2
- KDR | c.3481G>A p.G1161R | Missense Mutation (SNP) | VAF 195/552 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55766181, COSV55767832; called by muse, mutect2, varscan2
- KIAA1958 | c.1897C>T p.L633F | Missense Mutation (SNP) | VAF 216/600 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.793); catalogued as COSV61723839; called by muse, mutect2, varscan2
- KIF2B | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 199/508 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as rs749020826; called by muse, mutect2, varscan2
- KIF9 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 151/445 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV55523629; called by muse, mutect2, varscan2
- KLHDC1 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 88/256 reads (34%) | catalogued as COSV100833456; called by muse, mutect2, varscan2
- KMT2D | c.10606C>T p.R3536C | Missense Mutation (SNP) | VAF 286/667 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD114134, COSV56428871; called by muse, mutect2, varscan2
- KRT16 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 273/708 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs765533099; called by muse, mutect2, varscan2
- KRT32 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 150/379 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs933069187; called by muse, mutect2, varscan2
- KRT38 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 200/496 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1360976174; called by muse, mutect2, varscan2
- KRTAP12-3 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 173/439 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1230898294; called by muse, mutect2, varscan2
- KRTAP9-6 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 150/607 reads (25%) | SIFT deleterious (0.01); catalogued as rs1333155347; called by muse, mutect2
- LAMA1 | c.3467C>T p.S1156F | Missense Mutation (SNP) | VAF 221/596 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs771338059; called by muse, mutect2, varscan2
- LHPP | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV64328766; called by muse, mutect2
- LPCAT3 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV54643158; called by muse, mutect2, varscan2
- LRATD2 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 402/897 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59230454; called by muse, mutect2, varscan2
- LRCOL1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 203/544 reads (37%) | PolyPhen probably damaging (0.998); catalogued as rs1187829409, COSV64913129; called by muse, mutect2, varscan2
- LRP1 | c.8006C>T p.P2669L | Missense Mutation (SNP) | VAF 283/697 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs1255246023; called by muse, mutect2, varscan2
- LRP5 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 42/1294 reads (3%) | PolyPhen possibly damaging (0.483); catalogued as rs1396350476; called by muse, mutect2
- MANEAL | c.878G>A p.R293H (on ENST00000373045 / NM_001113482.1; = p.R71H on NM_152496.2) | Missense Mutation (SNP) | VAF 251/715 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs201707390, COSV100203787; called by muse, mutect2, varscan2
- MAST3 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 151/629 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1203837255; called by muse, mutect2, varscan2
- MED12 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 207/252 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs769202858, COSV61329448, COSV61343870, COSV61349385; called by muse, mutect2, varscan2
- MED6 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 127/362 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369104553; called by muse, mutect2, varscan2
- MEP1A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs769261432, COSV57920757; called by muse, mutect2, varscan2
- METTL22 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 126/422 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1567243303; called by muse, mutect2, varscan2
- MFAP1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs867192002, COSV99979744; called by muse, mutect2, varscan2
- MIDEAS | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 260/743 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs777809653; called by muse, mutect2, varscan2
- MIDN | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 237/558 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV56295429; called by muse, mutect2, varscan2
- MIER1 | c.1363C>T p.P455S (on ENST00000355356 / NM_001077701.3; = p.P472S on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1425265023; called by muse, mutect2, varscan2
- MLIP | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 197/492 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51432376; called by muse, mutect2, varscan2
- MLXIP | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 131/378 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV59837521; called by muse, mutect2, varscan2
- MRPL34 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 17/537 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53112920; called by muse, mutect2
- MTERF2 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1262068926; called by muse, mutect2, varscan2
- MUC12 | c.13447C>T p.P4483S (on ENST00000379442; = p.P4340S on NM_001164462.1) | Missense Mutation (SNP) | VAF 148/1139 reads (13%) | SIFT deleterious (0.02); catalogued as rs757302489; called by muse, mutect2, varscan2
- MUC16 | c.17767G>A p.E5923K | Missense Mutation (SNP) | VAF 15/482 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV67493263; called by muse, mutect2
- MUC4 | c.5509G>A p.D1837N | Missense Mutation (SNP) | VAF 161/931 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.55); catalogued as rs778906288, COSV62126546; called by muse, mutect2, varscan2
- MXD3 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 154/431 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as rs766190590; called by muse, mutect2, varscan2
- MYBPH | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 148/498 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1232482509; called by muse, mutect2
- MYH14 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs397516629, COSV51825622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 161/480 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766657133; called by muse, mutect2, varscan2
- MYL5 | c.372-1G>A p.X124_splice | Splice Site (SNP) | VAF 142/466 reads (30%) | catalogued as rs1257913824; called by muse, mutect2, varscan2
- MYLK | c.1679C>T p.T560I | Missense Mutation (SNP) | VAF 244/639 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1318184098; called by muse, mutect2, varscan2
- MYLK | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV60619145; called by muse, mutect2, varscan2
- MYO15B | c.6302C>T p.P2101L | Missense Mutation (SNP) | VAF 246/623 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs906284838; called by muse, mutect2, varscan2
- MYO18B | c.7304G>A p.R2435H | Missense Mutation (SNP) | VAF 283/654 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs764270244, COSV59138155; called by muse, mutect2, varscan2
- NAALADL1 | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 176/485 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs751635131, COSV60524445; called by muse, mutect2, varscan2
- NAV1 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 31/902 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs891105701; called by muse, mutect2
- NCOA6 | c.2642C>T p.T881M | Missense Mutation (SNP) | VAF 81/652 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs773056668; called by muse, mutect2, varscan2
- NCOA7 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 152/468 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); catalogued as COSV57653574; called by muse, mutect2, varscan2
- NFAT5 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 165/430 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63027108; called by muse, mutect2, varscan2
- NFKBIE | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 445/1101 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as rs1299986424; called by muse, mutect2, varscan2
- NIPA1 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 150/373 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1431568605; called by muse, mutect2, varscan2
- NOBOX | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 204/654 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99779162; called by muse, mutect2, varscan2
- NOL9 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 185/504 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs754607842; called by muse, mutect2, varscan2
- NOTCH2 | c.3647G>A p.G1216D | Missense Mutation (SNP) | VAF 19/602 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99864242; called by muse, mutect2
- NPB | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 38/1514 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.174); catalogued as rs997388116; called by muse, mutect2
- NRSN2 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 225/757 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244802488; called by muse, mutect2, varscan2
- NTSR1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 327/1254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370549384; called by muse, mutect2, varscan2
- NUP160 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV101021237; called by muse, mutect2, varscan2
- NYAP2 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 189/498 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56014855; called by muse, mutect2, varscan2
- OAZ1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 142/371 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs750595407; called by muse, mutect2, varscan2
- OBSCN | c.14503-1G>A p.X4835_splice | Splice Site (SNP) | VAF 179/446 reads (40%) | catalogued as COSV52832383; called by muse, mutect2, varscan2
- OR10H1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 180/763 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV100612467; called by muse, mutect2, varscan2
- OR12D2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 274/741 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV101011122; called by muse, mutect2, varscan2
- OR51T1 | c.816G>T p.R272S | Missense Mutation (SNP) | VAF 206/469 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs772529902, COSV59025161, COSV59027687; called by muse, mutect2, varscan2
- OR6S1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 188/492 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs947826348; called by muse, mutect2, varscan2
- OR9A4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 158/485 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV101516376; called by muse, mutect2, varscan2
- OXER1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 266/712 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs575064937; called by muse, varscan2
- P4HA3 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 258/769 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1179717289; called by muse, mutect2, varscan2
- PALB2 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 17/437 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55162606; called by muse, mutect2
- PALD1 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 239/681 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.394); catalogued as rs776845123; called by muse, mutect2, varscan2
- PAN2 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 146/397 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs138510771; called by muse, mutect2, varscan2
- PAQR9 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 283/734 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as COSV61417685; called by muse, varscan2
- PARP4 | c.1820G>A p.S607N | Missense Mutation (SNP) | VAF 144/372 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.122); catalogued as rs746146052; called by muse, mutect2, varscan2
- PCDH7 | c.2954G>A p.G985D | Missense Mutation (SNP) | VAF 202/537 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); catalogued as rs146009198; called by muse, mutect2, varscan2
- PCDHA6 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 287/670 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as COSV65348214, COSV65348221; called by muse, mutect2, varscan2
- PCDHB11 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 134/1928 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100697081; called by muse, mutect2
- PCDHB12 | c.2212del p.D738Tfs*2 | Frame Shift Del (DEL) | VAF 166/444 reads (37%) | catalogued as COSV99507737; called by mutect2, pindel, varscan2
- PCDHGA2 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 218/617 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); catalogued as rs1261595107, COSV53952300; called by muse, mutect2, varscan2
- PCLO | c.13255G>A p.A4419T | Missense Mutation (SNP) | VAF 131/649 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs555002741, COSV100430818, COSV61680756; called by muse, mutect2, varscan2
- PCSK1 | c.1934G>A p.S645N | Missense Mutation (SNP) | VAF 143/568 reads (25%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100227069; called by muse, mutect2, varscan2
- PCSK4 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 329/846 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1161448643; called by muse, mutect2, varscan2
- PDCD11 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 171/464 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1257531860, COSV63933860; called by muse, mutect2, varscan2
- PDE3B | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 146/434 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56389447, COSV99962032; called by muse, mutect2, varscan2
- PDE4D | c.2158C>T p.P720S (on ENST00000340635 / NM_001104631.2; = p.P584S on NM_006203.4) | Missense Mutation (SNP) | VAF 159/426 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.328); catalogued as rs1161941860; called by muse, mutect2, varscan2
- PEAK1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 184/491 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs763796402; called by muse, mutect2, varscan2
- PIGO | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 209/1248 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs150137667; called by muse, mutect2, varscan2
- PIK3CG | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 303/824 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs549157001, COSV63246361; called by muse, mutect2, varscan2
- PKHD1L1 | c.2986C>T p.Q996* | Nonsense Mutation (SNP) | VAF 113/309 reads (37%) | catalogued as COSV101007036; called by muse, mutect2, varscan2
- PLPPR2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 206/565 reads (36%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.508); catalogued as rs145102667; called by mutect2, varscan2
- PLVAP | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 23/788 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99391762; called by muse, mutect2
- POLR2M | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 21/720 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs1206041954; called by muse, mutect2
- POLR3B | c.2438G>A p.G813D | Missense Mutation (SNP) | VAF 139/364 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57279638; called by muse, mutect2, varscan2
- POR | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 141/413 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV67517543; called by muse, mutect2, varscan2
- PPP1R12C | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 207/637 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1198139590; called by muse, mutect2, varscan2
- PRDM14 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 165/561 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs865879860; called by muse, mutect2, varscan2
- PRDM2 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 21/710 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1433081682; called by muse, mutect2
- PRKAA1 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 205/526 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs371800275; called by muse, mutect2, varscan2
- PRKACB | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 108/327 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65759334; called by muse, mutect2, varscan2
- PRPS1L1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 239/513 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV72649864; called by muse, mutect2, varscan2
- PRRC2B | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 248/625 reads (40%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.984); catalogued as rs370475935; called by muse, mutect2, varscan2
- PRRT3 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 348/944 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs545656483; called by muse, mutect2, varscan2
- PSRC1 | c.850C>T p.P284S (on ENST00000409138 / NM_001363309.1; = p.P254S on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 345/853 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs1557746895; called by muse, mutect2, varscan2
- PTH1R | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 208/583 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1426137186; called by muse, mutect2, varscan2
- QSER1 | c.2776G>A p.V926I (on ENST00000399302; = p.V1055I on NM_001076786.3) | Missense Mutation (SNP) | VAF 159/514 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs766334143; called by muse, mutect2, varscan2
- RAD54L | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 202/648 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs771270089; called by muse, mutect2, varscan2
- RAI1 | c.2524C>T p.R842W | Missense Mutation (SNP) | VAF 318/794 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs538101375; called by muse, mutect2, varscan2
- RAI14 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs906507917; called by muse, mutect2, varscan2
- RANBP2 | c.3040G>A p.G1014R | Missense Mutation (SNP) | VAF 214/593 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs902769119; called by muse, mutect2, varscan2
- RARA | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 276/687 reads (40%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV54196552; called by muse, varscan2
- RARS1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV51565024; called by muse, mutect2, varscan2
- RBM12 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 209/798 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV58292714; called by muse, mutect2, varscan2
- RBM12 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 194/864 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as rs752177276; called by muse, mutect2, varscan2
- RBM27 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 222/623 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs1456967272; called by muse, mutect2, varscan2
- RGPD3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs751025041; called by muse, mutect2
- RIC1 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 110/172 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs781539842; called by muse, mutect2, varscan2
- RIPOR3 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 206/936 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV50408132; called by muse, mutect2, varscan2
- RNF213 | c.11777C>T p.T3926I | Missense Mutation (SNP) | VAF 146/402 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs373161624; called by muse, mutect2, varscan2
- RO60 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV66474253; called by muse, mutect2
- RPL10L | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 256/601 reads (43%) | catalogued as rs141953926, COSV53559245; called by muse, mutect2, varscan2
- RPP25L | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 251/1691 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs1427154616; called by muse, mutect2, varscan2
- RRP1B | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as rs1249380143; called by muse, mutect2
- RSPH9 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 172/478 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs930806409; called by muse, mutect2, varscan2
- RSPO2 | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 153/462 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV52654795, COSV99410522; called by muse, mutect2, varscan2
- RXFP4 | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 241/609 reads (40%) | catalogued as rs1301975565; called by muse, mutect2, varscan2
- RYR1 | c.4159G>A p.G1387S | Missense Mutation (SNP) | VAF 143/391 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1171218244; called by muse, mutect2, varscan2
- SDK1 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 160/459 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1002200901; called by muse, mutect2, varscan2
- SELENOK | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 88/239 reads (37%) | catalogued as rs761488603, COSV101530625, COSV72177882; called by muse, mutect2, varscan2
- SEMA6D | c.3049G>A p.V1017M (on ENST00000316364 / NM_153618.2; = p.V955M on NM_020858.2) | Missense Mutation (SNP) | VAF 184/555 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs371308825, COSV60374584; called by muse, mutect2, varscan2
- SERPINA11 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 169/466 reads (36%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.533); catalogued as rs1465254401; called by muse, mutect2, varscan2
- SH2D3A | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 32/1334 reads (2%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs1329246546, COSV99838049; called by muse, mutect2
- SH3KBP1 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 13/379 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as rs1235625002; called by muse, mutect2
- SH3PXD2B | c.1658C>T p.T553I | Missense Mutation (SNP) | VAF 272/732 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1336298982; called by muse, mutect2, varscan2
- SHC2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 217/523 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1427873164; called by muse, mutect2, varscan2
- SHOC1 | c.3439C>T p.Q1147* | Nonsense Mutation (SNP) | VAF 57/190 reads (30%) | catalogued as rs1487281815, COSV100597521; called by muse, mutect2, varscan2
- SIGLEC1 | c.1700G>A p.S567N | Missense Mutation (SNP) | VAF 328/1271 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs145038712; called by muse, mutect2, varscan2
- SIPA1L1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 186/598 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62170267; called by muse, mutect2, varscan2
- SKOR1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 28/874 reads (3%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs984129917; called by muse, mutect2
- SLA2 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 162/597 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs757714870, COSV53410043; called by muse, mutect2, varscan2
- SLC16A13 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 301/785 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs550979466; called by muse, mutect2, varscan2
- SLC16A6 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 177/431 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs1555748396; called by muse, mutect2, varscan2
- SLC4A7 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 205/527 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV55395447; called by muse, mutect2, varscan2
- SLC52A1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 199/519 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs888348535; called by muse, mutect2, varscan2
- SLC5A9 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 202/528 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as COSV52583666; called by muse, mutect2, varscan2
- SLIT1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 203/537 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56586658; called by muse, mutect2, varscan2
- SMAP2 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as rs148611104; called by muse, mutect2, varscan2
- SMARCA2 | c.3983C>T p.A1328V | Missense Mutation (SNP) | VAF 93/140 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV56647911; called by muse, mutect2, varscan2
- SMARCB1 | c.901G>A p.D301N (on ENST00000263121; = p.D347N on NM_003073.5) | Missense Mutation (SNP) | VAF 288/772 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV51954485; called by muse, mutect2, varscan2
- SMIM30 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 205/529 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs1324724400; called by muse, mutect2, varscan2
- SMPD3 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 200/565 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs781751221; called by muse, mutect2, varscan2
- SNX13 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 138/375 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as COSV101296783, COSV68064076; called by muse, mutect2, varscan2
- SPARCL1 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.617); catalogued as rs764713722; called by muse, mutect2, varscan2
- SPATA2L | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 416/1130 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs572857849; called by muse, mutect2, varscan2
- SPATA31D1 | c.3823C>T p.P1275S | Missense Mutation (SNP) | VAF 188/540 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.186); catalogued as rs752554115; called by muse, mutect2, varscan2
- SPECC1 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 225/307 reads (73%) | SIFT tolerated (0.29); PolyPhen benign (0.211); catalogued as COSV54963416; called by muse, mutect2, varscan2
- SPG11 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 20/759 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs1387107967, COSV99968518; called by muse, mutect2
- SPRY1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 210/548 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1437329042; called by muse, mutect2, varscan2
- SPTBN4 | c.6391C>T p.R2131C | Missense Mutation (SNP) | VAF 265/652 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1445269270; called by muse, mutect2, varscan2
- STARD9 | c.3613G>A p.D1205N | Missense Mutation (SNP) | VAF 243/609 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1214746100; called by muse, mutect2, varscan2
- STAT6 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 135/408 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1447559824; called by muse, mutect2, varscan2
- STOML2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 142/977 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59715756; called by muse, varscan2
- SVIL | c.6550G>A p.D2184N (on ENST00000355867 / NM_021738.3; = p.D1758N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/321 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1248137400; called by muse, mutect2, varscan2
- SYTL1 | c.1005G>A p.R335= (on ENST00000543823; = p.R323= on NM_032872.3) | Splice Region (SNP) | VAF 120/384 reads (31%) | catalogued as rs750533684; called by muse, mutect2
- TATDN1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as rs1476267324; called by muse, mutect2, varscan2
- TBC1D20 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 228/921 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62613495; called by muse, varscan2
- TBX15 | c.1153G>A p.G385S (on ENST00000369429 / NM_001330677.2; = p.G279S on NM_152380.3) | Missense Mutation (SNP) | VAF 190/522 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.333); catalogued as COSV52876419; called by muse, mutect2, varscan2
- TEX11 | c.1448C>T p.A483V (on ENST00000344304; = p.A468V on NM_031276.3) | Missense Mutation (SNP) | VAF 80/109 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV60231741; called by muse, mutect2, varscan2
- TGFB3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs138840538; called by muse, mutect2, varscan2
- TMEM234 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 216/504 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs763541749; called by muse, mutect2, varscan2
- TNRC6A | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 140/424 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV59369798; called by muse, mutect2, varscan2
- TNS3 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 142/199 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1190255024, COSV100235386; called by muse, mutect2, varscan2
- TOR1A | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 386/1051 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs1407588670; called by muse, mutect2, varscan2
- TPR | c.4328C>T p.T1443I | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs778391892; called by muse, mutect2, varscan2
- TRAC | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 185/514 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs61740301; called by muse, mutect2, varscan2
- TRAPPC11 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 98/271 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV58219105; called by muse, mutect2, varscan2
- TRAV12-3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 158/434 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.172); catalogued as rs1450699949; called by muse, mutect2, varscan2
- TRIM25 | c.1848G>A p.W616* | Nonsense Mutation (SNP) | VAF 28/558 reads (5%) | catalogued as COSV57546320; called by muse, mutect2
- TRIM37 | c.2192G>A p.R731K | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV99232962; called by muse, mutect2, varscan2
- TRIM67 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 27/738 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV100792079; called by muse, mutect2
- TRRAP | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 170/449 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.365); catalogued as rs1554408526; called by muse, mutect2, varscan2
- TTYH1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 429/1102 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV56610133; called by muse, mutect2, varscan2
- TUBB1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 207/828 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99414046; called by muse, mutect2, varscan2
- TXNIP | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 169/454 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1553765986; called by muse, mutect2, varscan2
- UBA7 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 319/857 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749167462; called by muse, mutect2, varscan2
- UBXN1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.703); catalogued as rs1244576773; called by muse, mutect2, varscan2
- UGT1A10 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 161/453 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs142662851; called by muse, mutect2, varscan2
- ULK2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 179/471 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100860658; called by muse, mutect2, varscan2
- VARS2 | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 206/589 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.12); catalogued as COSV100422924, COSV58913056; called by muse, mutect2, varscan2
- WASF2 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 184/508 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV71005296; called by muse, varscan2
- WDFY4 | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 219/586 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1277330810; called by muse, mutect2, varscan2
- WNK4 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 188/487 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1256967515; called by muse, mutect2, varscan2
- WWP1 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1474559815; called by muse, mutect2, varscan2
- XPO7 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 181/512 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as rs776561112; called by muse, mutect2, varscan2
- ZBP1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 117/504 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV59062254; called by muse, mutect2, varscan2
- ZBTB38 | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 190/509 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1262780151; called by muse, mutect2, varscan2
- ZC3H11A | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 164/438 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs778059892; called by muse, mutect2, varscan2
- ZC3H12B | c.1447G>A p.G483S | Missense Mutation (SNP) | VAF 334/432 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100161570; called by muse, mutect2, varscan2
- ZEB2 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 230/574 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100354907; called by muse, mutect2, varscan2
- ZNF285 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 201/530 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.081); catalogued as rs773023493; called by muse, mutect2, varscan2
- ZNF300 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 203/516 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs749612793; called by muse, mutect2, varscan2
- ZNF473 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 19/666 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as rs1398332853; called by muse, mutect2
- ZNF503 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 28/1186 reads (2%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs966154732; called by muse, mutect2
- ZNF527 | c.33G>A p.Q11= | Splice Region (SNP) | VAF 118/357 reads (33%) | catalogued as COSV99049998; called by muse, mutect2, varscan2
- ZNF620 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 205/568 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.323); catalogued as COSV58820609; called by muse, mutect2, varscan2
- ZNF714 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs1363546761; called by muse, mutect2, varscan2
- ZNF844 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.359); catalogued as COSV101462716; called by muse, mutect2, varscan2
- ABCA1 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 136/220 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA2 | c.5464G>A p.D1822N (on ENST00000614293; = p.D1792N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/538 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ABCB8 | c.1784C>T p.T595I (on ENST00000297504 / NM_001282291.2; = p.T578I on NM_007188.5) | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.065); called by muse, mutect2
- ACBD6 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ACCSL | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACD | c.586G>A p.G196S (on ENST00000620338; = p.G107S on NM_022914.3) | Missense Mutation (SNP) | VAF 292/748 reads (39%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ACTBL2 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 19/600 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ADAM29 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 212/502 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADAMTS15 | c.2771G>A p.G924E | Missense Mutation (SNP) | VAF 288/728 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.171); called by muse, varscan2
- ADAMTS20 | c.3829C>T p.P1277S | Missense Mutation (SNP) | VAF 219/578 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 153/412 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2582G>A p.G861E | Missense Mutation (SNP) | VAF 261/634 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 137/373 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADD2 | c.705+1G>A p.X235_splice | Splice Site (SNP) | VAF 151/347 reads (44%) | called by muse, mutect2, varscan2
- ADGRB1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 162/425 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ADGRD2 | c.2490G>A p.W830* | Nonsense Mutation (SNP) | VAF 253/746 reads (34%) | called by muse, mutect2, varscan2
- ADGRG2 | c.2294C>T p.S765F (on ENST00000379869 / NM_001079858.3; = p.S762F on NM_005756.4) | Missense Mutation (SNP) | VAF 163/224 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ADGRG4 | c.3260C>T p.T1087I | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.5); called by muse, mutect2
- ADGRV1 | c.3245del p.P1082Rfs*9 | Frame Shift Del (DEL) | VAF 175/482 reads (36%) | called by mutect2, pindel, varscan2
- ADH5 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 117/391 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ADORA2A | c.79_83del p.V27Lfs*73 | Frame Shift Del (DEL) | VAF 306/859 reads (36%) | called by mutect2, pindel, varscan2
- AFAP1L2 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- AFF1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 237/673 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, varscan2
- AFF1 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 204/564 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, varscan2
- AGBL3 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 144/362 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- AGPAT4 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- AK7 | c.1750A>G p.I584V | Missense Mutation (SNP) | VAF 138/284 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- AKAP9 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 12/442 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2
- AKT3 | c.46+1G>A p.X16_splice | Splice Site (SNP) | VAF 216/597 reads (36%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- ALG9 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- AMIGO2 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 229/571 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANAPC2 | c.1611G>A p.R537= | Splice Region (SNP) | VAF 16/522 reads (3%) | called by muse, mutect2
- ANK1 | c.4969G>A p.D1657N | Missense Mutation (SNP) | VAF 189/526 reads (36%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.7417C>T p.P2473S | Missense Mutation (SNP) | VAF 199/503 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANK2 | c.10894A>G p.N3632D | Missense Mutation (SNP) | VAF 154/374 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ANKRD11 | c.7021G>A p.A2341T | Missense Mutation (SNP) | VAF 140/453 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ANKS1B | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.979); called by muse, varscan2
- ANO6 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 144/349 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANXA13 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 121/331 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP001781.2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 176/423 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- APAF1 | c.447G>A p.W149* (on ENST00000551964 / NM_181861.2; = p.W138* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 17/623 reads (3%) | called by muse, mutect2
- APC2 | c.5869G>A p.A1957T | Missense Mutation (SNP) | VAF 24/832 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2
- APOBEC3B | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 173/938 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); called by muse, mutect2
- AREG | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 237/648 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ARGLU1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ARHGAP9 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 24/664 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.024); called by muse, mutect2
- ARL4D | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 163/446 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ARRDC1 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 270/756 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ARSI | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 22/814 reads (3%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); called by muse, mutect2
- ART5 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 218/560 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ASIC2 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 123/348 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ASPG | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 235/636 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATAD2B | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 97/302 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ATM | c.1803-1G>A p.X601_splice | Splice Site (SNP) | VAF 92/250 reads (37%) | called by muse, mutect2, varscan2
- ATP1B2 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2B4 | c.2247G>T p.K749N | Missense Mutation (SNP) | VAF 182/465 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATP7B | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 186/513 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATXN1L | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 241/601 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AURKB | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 175/505 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GAT3 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 186/522 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BAIAP3 | c.1952G>A p.S651N | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- BCL9 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 268/701 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BCLAF3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.146); called by muse, mutect2
- BICRAL | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 186/492 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BIRC6 | c.12187G>A p.E4063K | Missense Mutation (SNP) | VAF 171/483 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BLOC1S3 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 228/650 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRCC3 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- BRINP2 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 234/630 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BTBD9 | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 134/400 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- C12orf29 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1R | c.320G>A p.G107D (on ENST00000536053 / NM_001354346.2; = p.G93D on NM_001733.7) | Missense Mutation (SNP) | VAF 184/545 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- C2orf16 | c.3544C>T p.P1182S | Missense Mutation (SNP) | VAF 182/482 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- C2orf68 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 18/638 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- C6orf58 | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 167/500 reads (33%) | called by muse, mutect2, varscan2
- CA9 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 268/1774 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CABIN1 | c.5545C>T p.L1849F | Missense Mutation (SNP) | VAF 314/788 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1S | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 165/522 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CACNB2 | c.773C>T p.S258F (on ENST00000324631 / NM_201596.3; = p.S203F on NM_000724.4) | Missense Mutation (SNP) | VAF 20/596 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- CAD | c.2032-1G>A p.X678_splice | Splice Site (SNP) | VAF 129/366 reads (35%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.2091G>A p.M697I (on ENST00000236925 / NM_001297707.2; = p.M686I on NM_203459.3) | Missense Mutation (SNP) | VAF 149/439 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CAPRIN2 | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 104/391 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CAST | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 214/673 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CCDC28A | c.400T>G p.Y134D | Missense Mutation (SNP) | VAF 201/441 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CCDC74A | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 146/455 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CCDC85B | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 294/760 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCNF | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC123 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 154/466 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CEL | c.2207C>T p.A736V (on ENST00000673714; = p.A733V on NM_001807.6) | Missense Mutation (SNP) | VAF 201/617 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CELSR1 | c.4501G>A p.V1501M | Missense Mutation (SNP) | VAF 141/403 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CENPE | c.5548G>A p.E1850K | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CENPF | c.8886G>A p.M2962I | Missense Mutation (SNP) | VAF 153/429 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP162 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 127/363 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CEP57L1 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CFHR3 | c.629G>A p.C210Y | Missense Mutation (SNP) | VAF 112/313 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- CHAMP1 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 180/499 reads (36%) | called by muse, mutect2, varscan2
- CHD6 | c.5656G>A p.E1886K | Missense Mutation (SNP) | VAF 254/988 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CHEK2 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 234/636 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CHRND | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 219/507 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CIB4 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 240/651 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CIC | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 405/1067 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CIC | c.1837G>A p.G613S | Missense Mutation (SNP) | VAF 25/1008 reads (2%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2
- CKAP2L | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 122/411 reads (30%) | called by muse, mutect2, varscan2
- CLCN4 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2, varscan2
- CLIC6 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 388/1027 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CLN5 | c.123G>A p.W41* | Nonsense Mutation (SNP) | VAF 357/895 reads (40%) | called by muse, mutect2, varscan2
- CLN5 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 119/311 reads (38%) | called by muse, mutect2, varscan2
- CNGA1 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 160/446 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COG8 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 364/897 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL14A1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL16A1 | c.1887G>A p.G629= | Splice Region (SNP) | VAF 190/487 reads (39%) | called by muse, varscan2
- COL28A1 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 130/415 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COP1 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 143/359 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COPS3 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- COX6A2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 221/610 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CP | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 128/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPEB2 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 430/1076 reads (40%) | SIFT deleterious, low confidence (0.02); called by muse, varscan2
- CPEB4 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 178/465 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CPEB4 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CRACR2A | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 141/408 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CREB3L1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 301/736 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRPPA | c.1288G>A p.A430T (on ENST00000407010 / NM_001368197.1; = p.A380T on NM_001101417.4) | Missense Mutation (SNP) | VAF 109/349 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYBG1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 344/891 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1G2 | c.987G>A p.W329* | Nonsense Mutation (SNP) | VAF 246/628 reads (39%) | called by muse, mutect2, varscan2
- CSRNP1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 262/795 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CSTF3 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 126/326 reads (39%) | called by muse, mutect2, varscan2
- CTIF | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 23/882 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CYP3A43 | c.1331G>A p.G444D (on ENST00000354829 / NM_057095.3; = p.G445D on NM_022820.5) | Missense Mutation (SNP) | VAF 197/575 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CYP4F3 | c.1030del p.A345Qfs*18 | Frame Shift Del (DEL) | VAF 75/231 reads (32%) | called by mutect2, pindel, varscan2
- DCAF12 | c.576G>A p.W192* | Nonsense Mutation (SNP) | VAF 107/909 reads (12%) | called by muse, mutect2, varscan2
- DCD | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 98/326 reads (30%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCHS1 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 142/390 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCP2 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 190/484 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- DCPS | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 185/491 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DEXI | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 241/647 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DHH | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 345/841 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DHRS4L2 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 64/488 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- DISC1 | c.1632G>A p.R544= | Splice Region (SNP) | VAF 151/368 reads (41%) | called by muse, mutect2, varscan2
- DLG2 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 172/461 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DLGAP5 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 20/630 reads (3%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.486); called by muse, mutect2
- DNAAF5 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 225/576 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAJB12 | c.928C>T p.P310S (on ENST00000338820; = p.P276S on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/436 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.06); called by muse, mutect2
- DNHD1 | c.8155G>A p.D2719N | Missense Mutation (SNP) | VAF 246/706 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.154); called by muse, varscan2
- DNHD1 | c.12608G>A p.R4203K | Missense Mutation (SNP) | VAF 186/483 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNMBP | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 181/503 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DNMT1 | c.4297G>A p.G1433R | Missense Mutation (SNP) | VAF 234/708 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK9 | c.2368C>T p.L790F (on ENST00000376460 / NM_001366676.2; = p.L791F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/440 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPY19L2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DRC3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 251/713 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DSCAM | c.3877G>A p.G1293R | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- DSG2 | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 156/372 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUSP1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 197/589 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DYNC1H1 | c.6893G>A p.R2298H | Missense Mutation (SNP) | VAF 223/539 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.8893G>A p.V2965I | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DZANK1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 122/580 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- DZIP1L | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 191/545 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EFCAB9 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 29/736 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); called by muse, mutect2
- EFR3A | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EI24 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 166/446 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF3A | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 234/639 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EIF3B | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 167/638 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EOMES | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 393/1022 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, varscan2
- ERCC6 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 286/743 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.2404G>T p.G802* | Nonsense Mutation (SNP) | VAF 204/606 reads (34%) | called by muse, mutect2, varscan2
- ETV2 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 343/880 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EXOC8 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 288/721 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EXOC8 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 268/693 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- EXT1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 20/730 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2
- EZHIP | c.1394G>A p.S465N | Missense Mutation (SNP) | VAF 218/281 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- EZR | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 142/404 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FABP1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAHD2A | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 16/445 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- FAM126A | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 150/443 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAM171A1 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 127/374 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM217A | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 146/375 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FAM9B | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 21/471 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); called by muse, mutect2
- FAT1 | c.10350+1G>A p.X3450_splice | Splice Site (SNP) | VAF 115/297 reads (39%) | called by muse, mutect2, varscan2
- FAT2 | c.9475C>T p.H3159Y | Missense Mutation (SNP) | VAF 21/716 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FAT2 | c.9001G>A p.V3001I | Missense Mutation (SNP) | VAF 192/534 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.6797G>A p.G2266D | Missense Mutation (SNP) | VAF 174/455 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAT4 | c.4990G>A p.E1664K | Missense Mutation (SNP) | VAF 217/559 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- FDPS | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 250/638 reads (39%) | called by muse, mutect2, varscan2
- FDX2 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 295/660 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- FDXR | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 170/479 reads (35%) | called by muse, mutect2, varscan2
- FGF9 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 131/357 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- FHAD1 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 134/338 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FIBP | c.927G>A p.K309= (on ENST00000338369 / NM_198897.2; = p.K302= on NM_004214.5) | Splice Region (SNP) | VAF 154/382 reads (40%) | called by muse, varscan2
- FKBP6 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLNA | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FMN2 | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 366/918 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, varscan2
- FMO2 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FOXJ1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 294/844 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRAS1 | c.2768C>T p.T923I | Missense Mutation (SNP) | VAF 40/674 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); called by muse, mutect2
- FRAS1 | c.7099C>T p.Q2367* | Nonsense Mutation (SNP) | VAF 190/490 reads (39%) | called by muse, mutect2, varscan2
- FREM2 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 260/692 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.081); called by muse, mutect2
- FREM2 | c.2447G>A p.G816D | Missense Mutation (SNP) | VAF 20/766 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2
- FREM3 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 323/912 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.16130C>T p.A5377V | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSTL3 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 29/899 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.198); called by muse, mutect2
- GABPB2 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- GABRA3 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- GABRD | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 114/505 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNT3 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 157/448 reads (35%) | called by muse, mutect2, varscan2
- GAREM1 | c.2249G>A p.G750D (on ENST00000269209 / NM_001242409.2; = p.G749D on NM_022751.3) | Missense Mutation (SNP) | VAF 182/522 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- GATA2 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 391/990 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBF1 | c.1423G>A p.A475T (on ENST00000369983 / NM_001377137.1; = p.A474T on NM_004193.3) | Missense Mutation (SNP) | VAF 113/339 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- GIPC3 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 38/573 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- GJB7 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 189/554 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GK2 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 188/508 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLB1L2 | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 209/547 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLDC | c.2206G>A p.G736R | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GLI1 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 147/502 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- GLIS1 | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 341/880 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNA11 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 213/543 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNL2 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLPH3 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 141/553 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GOLPH3 | c.471T>C p.S157= | Splice Region (SNP) | VAF 96/508 reads (19%) | called by muse, mutect2, varscan2
- GORASP2 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 207/656 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GRIK4 | c.1868G>A p.G623D | Missense Mutation (SNP) | VAF 174/462 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GTF2H1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 174/489 reads (36%) | called by muse, mutect2, varscan2
- GTF2I | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 131/431 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- GXYLT2 | c.802T>A p.S268T | Missense Mutation (SNP) | VAF 184/435 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HARS1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 150/375 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- HDAC5 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 178/477 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HDGF | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 136/387 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR5A | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HES1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 152/428 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HIRA | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 173/422 reads (41%) | called by muse, mutect2, varscan2
- HKDC1 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGXB4 | c.1184_1188del p.E395Gfs*23 | Frame Shift Del (DEL) | VAF 50/182 reads (27%) | called by pindel, varscan2
- HNRNPUL1 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 338/836 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOMER3 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 198/547 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- HSD3B7 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 168/553 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- HSPA12B | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 388/1460 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- HSPA1A | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); called by mutect2, varscan2
- HSPA8 | c.411+1G>A p.X137_splice | Splice Site (SNP) | VAF 99/241 reads (41%) | called by muse, mutect2, varscan2
- HUWE1 | c.8705G>A p.G2902D | Missense Mutation (SNP) | VAF 15/438 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2
- HYAL1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 27/890 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IDUA | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 217/597 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFI16 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 81/225 reads (36%) | called by muse, mutect2, varscan2
- IFI16 | c.1952C>T p.A651V (on ENST00000295809 / NM_001364867.2; = p.A595V on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/483 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFRD2 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 254/696 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- IGF1R | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 196/554 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHM | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 204/489 reads (42%) | called by muse, mutect2, varscan2
- IGHV3OR15-7 | c.46+1G>A p.X16_splice | Splice Site (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2
- IGHV4-59 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 146/666 reads (22%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGSF9 | c.2486C>T p.P829L (on ENST00000368094 / NM_001135050.2; = p.P813L on NM_020789.4) | Missense Mutation (SNP) | VAF 25/891 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); called by muse, mutect2
- IL20RA | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 189/543 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ING4 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- INSR | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 177/457 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS5 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 263/672 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCE | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- IRAG1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 30/1079 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGAV | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 23/580 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.162); called by muse, mutect2
- JAK2 | c.2264G>A p.S755N | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2
- JHY | c.2239G>T p.E747* | Nonsense Mutation (SNP) | VAF 212/536 reads (40%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 174/423 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- JUP | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 180/478 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNH2 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 409/1159 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- KCNK3 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 33/1223 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- KCNK4 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 494/1260 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- KCNT1 | c.2041G>A p.E681K (on ENST00000488444; = p.E700K on NM_020822.3) | Missense Mutation (SNP) | VAF 332/822 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.334); called by muse, varscan2
- KDM1A | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 119/382 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1217 | c.5659G>A p.A1887T | Missense Mutation (SNP) | VAF 222/617 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIF13B | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 149/414 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KIF1B | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 20/582 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF24 | c.2870C>T p.S957F | Missense Mutation (SNP) | VAF 121/1009 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, varscan2
- KIF24 | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 109/1018 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, varscan2
- KIF26A | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 402/1106 reads (36%) | called by muse, mutect2
- KIF3A | c.1566+1G>A p.X522_splice | Splice Site (SNP) | VAF 99/229 reads (43%) | called by muse, mutect2, varscan2
- KLHL13 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 193/262 reads (74%) | SIFT tolerated (0.41); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- KNCN | c.165G>T p.L55F | Missense Mutation (SNP) | VAF 233/518 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP9-7 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 116/817 reads (14%) | SIFT deleterious (0); called by muse, varscan2
- L2HGDH | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 133/390 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- LATS1 | c.821_824del p.T274Sfs*10 | Frame Shift Del (DEL) | VAF 178/480 reads (37%) | called by pindel, varscan2
- LCA5L | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 173/452 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LIPC | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 205/542 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LIPM | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMNB2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 224/603 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- LONP2 | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 150/445 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- LRIG2 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- LRR1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRRTM1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 25/1050 reads (2%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.942); called by muse, mutect2
- LTK | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 172/408 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- LZTR1 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 193/529 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MAD1L1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 343/959 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MAFG | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 187/520 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAOA | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 201/275 reads (73%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- MAP3K20 | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 146/362 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAP4K1 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 177/477 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAST4 | c.2023G>A p.A675T (on ENST00000403625 / NM_001164664.2; = p.A486T on NM_015183.3) | Missense Mutation (SNP) | VAF 98/394 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MB | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 183/464 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, varscan2
- MBOAT2 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MDC1 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 334/865 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MDFIC | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 266/653 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEF2D | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 223/560 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- MEFV | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 89/477 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MEGF6 | c.3369G>A p.W1123* | Nonsense Mutation (SNP) | VAF 210/636 reads (33%) | called by muse, mutect2
- MEPCE | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 379/1027 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MICU2 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 205/615 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MIF4GD | c.303G>A p.W101* (on ENST00000325102 / NM_001370592.1; = p.W135* on NM_020679.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 232/674 reads (34%) | called by muse, mutect2, varscan2
- MINDY3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 179/513 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MLYCD | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 173/498 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MNT | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 348/935 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- MOGAT3 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MORC3 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 129/377 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPHOSPH8 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MROH2A | c.3244C>T p.L1082F | Missense Mutation (SNP) | VAF 205/610 reads (34%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.999); called by muse, mutect2
- MROH5 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 177/481 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPS35 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 216/610 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MSH6 | c.3653G>A p.G1218D | Missense Mutation (SNP) | VAF 160/405 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSS51 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 121/352 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCH2 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MTF1 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 201/567 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MTSS2 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 30/1080 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- MUC16 | c.11275A>G p.T3759A | Missense Mutation (SNP) | VAF 163/526 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); called by muse, mutect2
- MUC6 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 239/667 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MUTYH | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 187/525 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- MYCT1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 23/736 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYLK4 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- MYLPF | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 25/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYO16 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 148/421 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MYO1G | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 301/865 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MZF1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 373/1042 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NAA25 | c.2783C>T p.T928I | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAT10 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 220/607 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- NCBP3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NCKAP1 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCOA2 | c.2906C>T p.T969I | Missense Mutation (SNP) | VAF 22/723 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2
- NCOA3 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 122/545 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NCOA5 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 132/559 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- NDNF | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 152/465 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NDUFA9 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- NDUFAF6 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NECAB3 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 347/1255 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- NECAP2 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 144/363 reads (40%) | called by muse, mutect2, varscan2
- NECTIN4 | c.1002C>T p.D334= | Splice Region (SNP) | VAF 175/455 reads (38%) | called by muse, mutect2, varscan2
- NEIL2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- NEMF | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFAM1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 203/585 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- NFIA | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 215/539 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NFKBIL1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 514/1293 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- NGF | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 128/324 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NHSL1 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 198/505 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIT1 | c.574A>T p.S192C | Missense Mutation (SNP) | VAF 180/437 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NKX1-1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 339/902 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLN | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NOL9 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 324/1077 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOS3 | c.2897-1G>A p.X966_splice | Splice Site (SNP) | VAF 212/579 reads (37%) | called by muse, mutect2, varscan2
- NRP1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 152/435 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUP133 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 183/545 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- NWD2 | c.4298G>A p.C1433Y | Missense Mutation (SNP) | VAF 194/478 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NXT1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 225/862 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OCA2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 55/602 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- OLFML1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 186/487 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OPN4 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 166/465 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR14A16 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 181/436 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- OR4D10 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 165/432 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- OR4E1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4F15 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 143/376 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OR4K5 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 170/656 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- OR5L2 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 143/438 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- OR8U1 | c.61_69del p.Q21_L23del | In Frame Del (DEL) | VAF 110/432 reads (25%) | called by pindel, varscan2
- ORC2 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OSMR | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- OTOF | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OTOG | c.6934G>A p.V2312M | Missense Mutation (SNP) | VAF 238/621 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OXT | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 246/1223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAQR7 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 231/603 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARD6A | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 204/577 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PARP10 | c.2318G>A p.G773D | Missense Mutation (SNP) | VAF 161/813 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PBRM1 | c.4415C>T p.P1472L | Missense Mutation (SNP) | VAF 232/600 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PCDH15 | c.5090C>T p.S1697F | Missense Mutation (SNP) | VAF 173/489 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- PCDHB16 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 217/512 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PCNX2 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2
- PCSK4 | c.1502G>A p.S501N | Missense Mutation (SNP) | VAF 357/984 reads (36%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDZD7 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 147/380 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PEF1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 139/386 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PGGHG | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 135/434 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGLYRP4 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- PIEZO2 | c.6191G>A p.R2064K | Missense Mutation (SNP) | VAF 255/704 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PIK3C3 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 147/448 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD1 | c.7814C>T p.P2605L | Missense Mutation (SNP) | VAF 279/742 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
790 further variants in this file (215 protein-altering or splice-affecting, 516 silent, 59 other) are not listed here.
